Surgical pathology report (de-identified scan), TCGA case TCGA-28-5207, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5207-01A (Primary Tumor).

[page 1 of 5]
Patient: [REDACTED]

Accession Number: [REDACTED]

Hospital No: [REDACTED]

Pathologist: [REDACTED]

Ordering M.D.: [REDACTED]

Date of Birth: [REDACTED]

Assistant: [REDACTED]

Age/Sex: [REDACTED]

Date of Procedure: [REDACTED]

Copies To: [REDACTED]

Date Received: [REDACTED]

TCGA-28-5207

Location: [REDACTED]

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. SKIN, LEFT FRONTAL, EXCISION:

- Seborrheic keratosis
- This benign skin lesion extends to the right excisional margin

B. BRAIN, LEFT FRONTAL-TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

C. BRAIN, LEFT TEMPORAL, EXCISION, NCI #1:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 90% of tumor cellularity

D. BRAIN, LEFT TEMPORAL, EXCISION, NCI #2:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 90% of tumor cellularity

E. BRAIN, LEFT TEMPORAL, EXCISION, NCI #3:

- Glioblastoma multiforme, WHO grade IV
- 40% of tumor necrosis
- 95% of tumor cellularity

F. BRAIN, LEFT TEMPORAL, EXCISION, NCI #4:

- Glioblastoma multiforme, WHO grade IV
- 70% of tumor necrosis
- 95% of tumor cellularity

G. BRAIN, LEFT TEMPORAL, EXCISION, NCI #5:

- Glioblastoma multiforme, WHO grade IV
- 30% of tumor necrosis
- 95% of tumor cellularity

H-J. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for [REDACTED] has been reported to be associated with a relatively diminished response to [REDACTED]. The 60% result in this case suggests the possibility of a relatively diminished response to [REDACTED].

Patient Case(s): [REDACTED]

Copy For: [REDACTED]

Page 1 of 5

[page 2 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors. Hence the preserved expression of PTEN in this case, when combined with EGFRvIII mutation, permits a possibility of this tumor being responsive to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas.

subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell.

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas.

Association between laminin-8 and glial tumor grade, recurrence, and patient survival.

Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) often is indicative of an upregulation of receptor tyrosine kinase signaling. It has been shown to be associated with a relative resistance to radiation therapy in glioblastoma multiforme.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

HISTORY:

Pre-operative diagnosis: left frontal tumor

MICROSCOPIC FINDINGS:

These focally necrotic infiltrating high-grade astrocytoma shows enlarged hyperchromatic pleomorphic nuclei showing numerous mitotic figures and associated with florid endothelial proliferation.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
MGMT	J8	Up to 60%
PTEN	J8	Retained (3+)
pMAPK	J8	Up to 80% of tumor nuclei and 90% of cytoplasm is positive
Laminin beta-1 (8/411)	J8	Upregulated (2+) with some glial cells positive
Laminin beta-2 (9/421)	J8	Focal paranuclear retention (1+)
EGFR by FISH	J8	Pending

GROSS:

A. LEFT FRONTAL SKIN LESION

Labeled with the patient's name, labeled "left frontal skin lesion" and received fresh for intraoperative consultation and subsequently submitted in formalin is an oriented hair-bearing pale tan skin ellipse with attached subcutaneous tissue measuring 2.3 x 0.7 cm and excised to a depth of 0.7 cm.

[page 3 of 5]
PATIENT: [REDACTED] ***** Addendum - Please See End of Report *****
ACCESSION #: [REDACTED]

Along the skin surface there is a centrally located flesh colored papule measuring 0.6 x 0.4 cm and comes within 1.0 cm of the front tip, abuts the right margin, 0.3 cm away from the back tip and 0.1 cm away from the left margin. Entirely submitted.

Ink key:

Black: Deep.
Yellow: Front.
Green: Back.
Red: Left.
Blue: Right.

Slide key:

A1. Frozen remnant - 1
A2. Front tip, bisected - 2
A3. Back tip, bisected - 2
A4, A5. Remaining sections - 3 each

B. LEFT FRONTAL TEMPORAL FS

Labeled with the patient's name, labeled "left temporal FS" and received fresh for intraoperative consultation and subsequently submitted in formalin is a 1.4 x 0.5 x 0.3 cm aggregate of multiple soft pale tan slightly hemorrhagic tissue fragments. Entirely submitted.

Slide key:

B1. Frozen remnant - multiple
B2. Remaining tissue - multiple

C. LEFT TEMPORAL NCI #1

Labeled with the patient's name, labeled "left temporal NCI #1" and received in formalin is a 1.2 x 0.7 x 0.3 cm aggregate of multiple soft pale tan-pink slightly hemorrhagic tissue fragments. Entirely submitted.
C1. Multiple

D. LEFT TEMPORAL NCI #2

Labeled with the patient's name, labeled "left temporal NCI #2" and received in formalin is a 1.1 x 0.5 x 0.3 cm irregular portion of soft pink-tan slightly hemorrhagic tissue. Entirely submitted.
D1. 2

E. LEFT TEMPORAL NCI #3

Labeled with the patient's name, labeled "left temporal NCI #3" and received in formalin is a 0.9 x 0.7 x 0.4 cm irregular portion of soft pink-tan slightly hemorrhagic tissue. Entirely submitted.
E1. 2

F. LEFT TEMPORAL NCI #4

Labeled with the patient's name, labeled "left temporal NCI #4" and received in formalin is a 0.8 x 0.6 x 0.4 cm irregular portion of soft pink-tan slightly hemorrhagic tissue. Entirely submitted.
F1. 2

G. LEFT TEMPORAL NCI #5

Labeled with the patient's name, labeled "left temporal NCI #5" and received in formalin is a 1.0 x 0.8 x 0.3 cm irregular portion of soft pink-tan slightly hemorrhagic tissue. Entirely submitted.
G1. 2

H. LEFT TEMPORAL PERMANENT

Labeled with the patient's name, labeled "left temporal permanent" and received in formalin is a 1.6 x 1.1 x 0.3 cm aggregate of soft pale tan slightly hemorrhagic tissue. Entirely submitted.

[page 4 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

H1. Multiple

I. LEFT TEMPORAL, CLINICAL TRIAL

Labeled with the patient's name, labeled "left temporal clinical trial" and received in formalin is a 1.4 x 0.5 x 0.4 cm irregular portion of soft pale tan hemorrhagic tissue. Entirely submitted.

I1. 1

J. LEFT TEMPORAL MASS

Labeled with the patient's name, labeled "left temporal mass" and received in formalin is an unoriented portion of the temporal lobe measuring 4.3 x 3.7 x 2.9 cm. The gyri are slightly dilated. The cut surface reveals diffusely necrotic slightly friable pale tan tissue. Entirely submitted.

Slide key:

J1-J14. 1, 2, 1, 1, 2, 3, 1, 3, 1, 1, 1, 1, 1, 1

Gross dictated by [REDACTED]

INTRAOPERATIVE CONSULTATION:

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN AND TP):

A) LEFT FRONTAL SKIN FS:

- Seborrheic keratosis, extending to the right excisional margin

B) LEFT TEMPORAL FS + TP:

- Glioblastoma

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

[REDACTED] Electronically signed [REDACTED]

[page 5 of 5]
PATIENT: [REDACTED] ***** Addendum - Please See End of Report *****
ACCESSION #: [REDACTED]

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) for EGFR in BRAIN

Tissue Block: J8

RESULTS: POSITIVE for EGFR Amplification (See note below)

Number of cells evaluated: 40

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a brain tumor sample from this patient with Abbott Molecular probes specific for the centromere of chromosome 7 (control probe) and the short arm (EGFR-7p12) of chromosome 7 was performed. The control sample gave expected results.

These studies showed amplification of the EGFR gene with a 8.1 ratio of EGFR signals to the centromere signals in 72.5% of the nuclei examined.

NOTE:

1. Samples are considered positive in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells or tumors with four or more copies of the EGFR gene in $\geq 40\%$ of the cells (high polysomy).
2. Samples are considered inconclusive, requiring consult with the pathologist, in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $<10\%$ of analyzed cells or when four or more copies of the EGFR gene in $< 40\%$ of the cells.

References:

[REDACTED]

These FISH tests were developed and their performance characteristics determined by [REDACTED] as required by the CLIA [REDACTED] regulations. They have not been cleared or approved for specific uses by the U.S. Food and Drug Administration.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

[REDACTED]

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED]. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file 833360c3-aa79-4961-979a-349abd6ddb82 (TCGA-28-5207.0BAFBC8D-023D-4C05-A802-5C32767C0E55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).